Gene-level copy-number profile of tumor specimen TARGET-40-PASEBY-01A from TARGET case TARGET-40-PASEBY, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.6 years (4,249 days).
Specimen TARGET-40-PASEBY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.41030be7-181a-5aa6-916d-b2404e782f98.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASEBY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/8bc89e7a-2439-47c3-85e9-c67543473b73

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 69; copy number 2: 2,825; copy number 3: 10,679; copy number 4: 6,478; copy number 5: 14,159; copy number 6: 20,544; copy number 7: 3,070; copy number 8: 450; copy number 9: 483; copy number 10: 693; copy number 11: 107; copy number 12: 231; copy number 13: 23; copy number 15: 50; copy number 16: 65; copy number 17: 30; copy number 18: 34; copy number 23: 149; copy number 25: 10; copy number 31: 2; copy number 41: 29.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–23,849,914, 25 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.
- chr17:7,686,071–7,885,238, 9 genes: WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 392 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 18 (within-gene range 6–18): AC244205.1.
- chr2:88,857,161–89,196,829, 33 genes, copy number 18: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr6:40,713,411–47,832,780, 192 genes, copy number 16–41 (broad region; genes not listed).
- chr9:14,475–1,333,953, 30 genes, copy number 13–25 (within-gene range 11–25): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr10:92,204,229–93,059,493, 16 genes, copy number 17 (within-gene range 3–17): AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12, MARK2P9, AL161652.1, IDE, KIF11, RPL11P4, RN7SL644P, EIF2S2P3, HHEX, Y_RNA, EXOC6, AL392103.1.
- chr15:57,706,695–57,782,762, 2 genes, copy number 13: POLR2M, AC090651.1.
- chr15:74,062,780–75,021,495, 49 genes, copy number 15 (within-gene range 9–15): DNM1P33, GOLGA6A, RN7SL429P, COMMD4P2, ISLR2, AC010931.1, AC010931.2, Metazoa_SRP, ISLR, STRA6, CCDC33, AC023300.3, AC023300.1, AC023300.2, CYP11A1, PPIAP46, AC090826.1, AC090826.2, LINC02255, SEMA7A, MIR6881, AC090826.3, UBL7, UBL7-AS1, AC012435.2, AC012435.3, AC012435.1, ARID3B, CLK3, AC100835.2, AC100835.1, EDC3, CYP1A1, CYP1A2, CSK, MIR4513, LMAN1L, AC091230.1, CPLX3, ULK3, MIR6882, SCAMP2, MPI, FAM219B, COX5A, RPP25, SCAMP5, AC015720.2, Y_RNA.
- chr15:100,372,936–100,437,914, 1 gene, copy number 15 (within-gene range 6–15): CERS3-AS1.
- chr18:47,390–2,489,426, 48 genes, copy number 16–17 (within-gene range 10–17): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr21:19,046,310–20,828,622, 19 genes, copy number 16: AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1.
- chr21:21,223,295–21,226,829, 1 gene, copy number 13: AP001136.1.

Autosomal genes at a single copy (total copy number 1): 69. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
